Somatic mutation profile of tumor specimen C3N-01656-01 (aliquot CPT0121610006) from CPTAC case C3N-01656, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.9 years (25,181 days).
Specimen C3N-01656-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 016b9b25-3009-4ba5-b0f8-1e434cf96a91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01656-31 (Blood Derived Normal), aliquot CPT0121650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/846bc9dd-4256-48e2-8ee5-bb88f4875c47

The open-access MAF lists 112 somatic variants for this specimen: 84 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 16, Nonsense Mutation 8, Intron 7, RNA 4, Frame Shift Del 4, Splice Region 4, Frame Shift Ins 2, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 53/649 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748420898; called by muse, mutect2
- ACE | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs558593002; called by muse, mutect2
- DST | c.2722del p.D908Tfs*56 (on ENST00000361203 / NM_001374722.1; = p.D582Tfs*56 on NM_001723.6) | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as COSV99749333; called by mutect2, pindel, varscan2
- DYNC1H1 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104420293; called by muse, mutect2, varscan2
- ESRP1 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100619147; called by muse, mutect2, varscan2
- FXN | c.221C>T p.T74M (on ENST00000377270; = p.T149M on NM_000144.5) | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551991546, COSV101040031; called by muse, mutect2, varscan2
- PLN | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV62646810; called by muse, mutect2, varscan2
- QRICH2 | c.3280G>A p.V1094I | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs140513687; called by muse, mutect2, varscan2
- SFMBT2 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV62805598; called by muse, mutect2, varscan2
- TBC1D14 | c.1629T>A p.F543L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68985923; called by muse, mutect2, varscan2
- TEX264 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199677902; called by muse, mutect2
- TICRR | c.3110C>T p.S1037F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759880434; called by muse, mutect2, varscan2
- TNFRSF1A | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.427); catalogued as COSV50602242; called by muse, mutect2, varscan2
- VHL | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 150/356 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as CM961421, COSV56543987, COSV56547178, COSV56569780; called by muse, mutect2, varscan2
- ZNF16 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767065173; called by muse, mutect2, varscan2
- ABCC10 | c.2761G>T p.E921* (on ENST00000372530 / NM_001198934.2; = p.E893* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.902-5T>A | Splice Region (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- ALOX12B | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ALS2 | c.3489T>A p.Y1163* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- ANKRD11 | c.1516C>G p.P506A | Missense Mutation (SNP) | VAF 82/365 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARHGEF11 | c.2033+1del p.X678_splice | Splice Site (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- BUB3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- C19orf47 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.292); called by muse, mutect2
- CCSER2 | c.70A>T p.R24* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CHST11 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- CLCN7 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 58/932 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP5 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- DAGLA | c.1290G>A p.K430= | Splice Region (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- DUOX2 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 133/454 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- E4F1 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EID1 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERCC2 | c.1637A>T p.E546V | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ESS2 | c.253A>C p.I85L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- F12 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- FADS1 | c.762T>G p.H254Q | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- FLNA | c.2276T>C p.F759S | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GNAI3 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGB1 | c.8080A>G p.M2694V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HNRNPK | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXA5 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 149/288 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ILK | c.532+7C>T | Splice Region (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- INF2 | c.1676_1682del p.P559Hfs*4 | Frame Shift Del (DEL) | VAF 57/291 reads (20%) | called by mutect2, pindel, varscan2
- INPP4A | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCD | c.656A>C p.N219T | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.085); called by muse, mutect2
- KDM5C | c.1641del p.V548* | Frame Shift Del (DEL) | VAF 97/280 reads (35%) | called by mutect2, pindel, varscan2
- LAMA2 | c.4400A>C p.Q1467P | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- LENG8 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LPIN1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MCM9 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MIA3 | c.4551G>T p.R1517S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MRTFB | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC4 | c.14961C>A p.D4987E (on ENST00000463781 / NM_018406.7; = p.D751E on NM_004532.6) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC4 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MYH9 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 88/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOTCH1 | c.5613C>A p.C1871* | Nonsense Mutation (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- PAK1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PDZD8 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PIK3C2B | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2
- PTPRD | c.3242A>G p.Y1081C | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RELN | c.9557C>G p.S3186* | Nonsense Mutation (SNP) | VAF 30/607 reads (5%) | called by muse, mutect2
- RIPOR1 | c.3297delinsTT p.R1100Sfs*46 (on ENST00000379312 / NM_001193522.2; = p.R1096Sfs*46 on NM_024519.4) | Frame Shift Ins (INS) | VAF 17/101 reads (17%) | called by mutect2*, pindel, varscan2*
- RUNDC3B | c.1371C>A p.Y457* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- SCNN1A | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SCUBE3 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SEC23A | c.1613_1615del p.E538del | In Frame Del (DEL) | VAF 46/239 reads (19%) | called by pindel, varscan2
- SELENON | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA7A | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- SLC25A39 | c.649C>G p.L217V (on ENST00000377095 / NM_001143780.3; = p.L209V on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- SLC25A46 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, varscan2
- SLITRK6 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TANK | c.1190A>C p.E397A | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TESPA1 | c.1426T>C p.S476P (on ENST00000316577 / NM_001098815.3; = p.S338P on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.555); called by muse, mutect2
- TMEM259 | c.843C>T p.G281= | Splice Region (SNP) | VAF 60/248 reads (24%) | called by muse, mutect2, varscan2
- TMSB4X | c.81T>G p.N27K | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFRSF25 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.11913A>T p.E3971D | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UGGT2 | c.4415A>C p.K1472T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- UNC13A | c.3138C>A p.D1046E | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- XAB2 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- ZBED8 | c.980del p.F327Sfs*5 | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.2195A>T p.K732I | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ZNF221 | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ZNF318 | c.27dup p.V10Rfs*7 | Frame Shift Ins (INS) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- ADAMTS4 | c.1605C>A p.T535= | Silent (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1899T>C p.D633= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- KLB | c.2709G>A p.R903= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- LTB4R | c.162C>A p.A54= | Silent (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- MADD | c.3166C>A p.R1056= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- MAPK1 | c.153A>G p.V51= | Silent (SNP) | VAF 20/82 reads (24%) | called by mutect2, varscan2
- MED10 | c.285T>G p.V95= | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- PLXNA1 | c.396C>T p.S132= | Silent (SNP) | VAF 84/216 reads (39%) | catalogued as rs755191074; called by muse, mutect2, varscan2
- RABEPK | c.966A>G p.E322= | Silent (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
- STOX2 | c.513C>A p.T171= | Silent (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- TDO2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV70809347; called by muse, mutect2, varscan2
- UBE3A | c.504G>T p.R168= | Silent (SNP) | VAF 73/252 reads (29%) | called by muse, mutect2, varscan2
- WDR64 | c.1254T>C p.S418= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV63794473; called by muse, mutect2, varscan2
- ZBTB8B | c.327C>T p.D109= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as rs1157279873; called by muse, mutect2
- ZNF845 | c.2697A>G p.Q899= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101508907; called by muse, mutect2, varscan2
- ZNFX1 | c.4953G>A p.Q1651= | Silent (SNP) | VAF 128/432 reads (30%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-524C>T | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- BTN3A2 | c.964+23C>A | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- F12 | c.530-27G>A | Intron (SNP) | VAF 41/228 reads (18%) | catalogued as rs1218073932; called by muse, mutect2, varscan2
- FAM86C2P | n.113G>A | RNA (SNP) | VAF 37/253 reads (15%) | catalogued as rs773429273; called by muse, mutect2, varscan2
- ISCA1P1 | n.178C>T | RNA (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- LGALS3 | c.597+731G>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- LINC01587 | n.275C>A | RNA (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- PDE8A | c.942-22dup | Intron (INS) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- SLC43A2 | c.1217+44C>A | Intron (SNP) | VAF 78/192 reads (41%) | called by muse, mutect2, varscan2
- STAG3L2 | n.702T>A | RNA (SNP) | VAF 52/1006 reads (5%) | called by muse, mutect2
- TMEM135 | c.*4502C>A | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- VEZT | c.169-563G>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
